CCDI case PBBLHI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/b01abffd-884b-4d8d-817b-4befab08791b

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 17.0 years (6,216 days).

Biospecimens (3 samples)
- Sample 0DBFC9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBFCE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBFCG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
